CCDI case PBBYCP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined sites within respiratory system and intrathoracic organs.
https://portal.gdc.cancer.gov/cases/0d135df8-486c-4594-9dcb-f7dc59c7e8e5

Demographics
Sex at birth: male; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Pleuropulmonary blastoma: ICD-O-3 morphology code: 8973/3; Tissue or organ of origin: Lower lobe, lung; Age at diagnosis: 0.0 years (2 days).

Biospecimens (3 samples)
- Sample 0DNCGU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNCOS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DSHSQ: Tissue type: Tumor; Specimen type: Solid Tissue.
